CCDI case PBBVMZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/30a335e4-1f95-44ef-8ace-1569f3d815dd

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,675 days).

Biospecimens (3 samples)
- Sample 0DII37: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DII3J: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DII46: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
